Gene-level copy-number profile of tumor specimen TCGA-LN-A7HV-01A from TCGA case TCGA-LN-A7HV, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G1; Age at diagnosis: 58.8 years (21,462 days).
Specimen TCGA-LN-A7HV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.37de86f0-ad1c-4597-bad1-872ca5483823.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-LN-A7HV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9895e3a0-72f4-42a3-b71d-3fbf738cd2d3

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 13; copy number 2: 17,333; copy number 3: 3,513; copy number 4: 33,684; copy number 5: 2,296; copy number 6: 2,761; copy number 7: 44; copy number 8: 117; copy number 9: 13; copy number 11: 28.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-LN-A7HV-01A-21D-A350-01): tumor purity 0.64, ploidy 1.78, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:204,545,475–205,620,162, 1 gene (within-gene range 0–2): PARD3B.
- chr2:205,253,304–205,253,503, 1 gene: AC008171.1.
- chr3:8,359,344–8,366,427, 2 genes: AC023481.1, RNU4ATAC17P.
- chr4:86,117,912–86,219,926, 1 gene (within-gene range 0–2): MAPK10-AS1.
- chr5:93,617,725–94,111,699, 1 gene (within-gene range 0–2): FAM172A.
- chr5:93,860,669–94,618,597, 3 genes (within-gene range 0–2): AC114980.1, AC117528.1, KIAA0825.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 41 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:189,631,389–189,897,276, 1 gene, copy number 9 (within-gene range 5–9): TP63.
- chr3:189,829,922–189,830,009, 1 gene, copy number 9: MIR944.
- chr3:189,969,030–189,969,861, 1 gene, copy number 9: MTAPP2.
- chr5:271,621–997,308, 28 genes, copy number 11 (within-gene range 4–11): PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, AC026740.2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1.
- chr6:160,991,727–161,274,061, 2 genes, copy number 9: MAP3K4, AGPAT4.
- chr6:161,353,679–161,446,016, 2 genes, copy number 9: AL132982.1, AL138716.1.
- chr9:135,808,487–135,961,373, 3 genes, copy number 9: CAMSAP1, AL355574.1, UBAC1.
- chr12:27,935,523–27,972,733, 3 genes, copy number 9: AC008011.1, PTHLH, AC008011.2.

Autosomal genes at a single copy (total copy number 1): 13. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
